Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M1, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M1-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:

Anterior mediastinal dissection.

Specimen Received:

- A: Thymus and tumor (FS)
- B: Superior thymus margin
- C: Lateral thymus
- D: Pericardial phrenic margin (FS)

Final Pathologic Diagnosis:

- A. Thymus and tumor, resection:

Thymoma (see Note for classification).

Maximum tumor dimension = 5.3 cm.

Surgical margins of resection are negative for tumor (see also parts

- B, C, and D below).

Frozen section diagnosis is confirmed.

Benign multilocular thymic cysts.

One benign lymph node is also present.

- B. Thymus, superior margin, resection:

Benign fat.

Negative for tumor.

- C. Thymus, lateral, resection:

Negative for tumor (benign fat).

- D. Mediastinum, pericardial phrenic margin, excision:

Negative for tumor.

Frozen section diagnosis is confirmed.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

Biopsies of this thymoma, including both H&E and immunohistochemical stains, were previously reviewed. The tumor was classified as Thymoma WHO type mixed A/B. Immunohistochemical stains are not repeated at this time.

Intraoperative Consult Diagnosis:

FSA: Thymus and tumor:

Thymoma.

The designated inked resection margin with no tumor seen.

TAT: 38 mins.

FSD: Pericardial phrenic margin:

Nerve and vascular soft tissue with no tumor seen.

TAT: 30 mins.

ICD O-3
Thymoma, type AB NOS
044E 8582/1
Site Anterior mediastinum C581
Thymus C37.9
JW 6/10/14

[page 2 of 2]
Gross Description:

A. Received fresh, labeled "thymus and tumor," is a 17.5 x 11.5 x 4.4 cm tan, lobulated, irregular fatty tissue partially surfaced by a tan-pink, smooth, glistening serosa. Sectioning reveals a 5.3 x 5.1 x 3.7 cm tan-white, homogeneous, rubbery, faintly nodular mass which abuts the serosa and inked resection margin. Within the fat adjacent to the mass are multiple smooth walled, uni/multilobulated cysts, up to 3 cm. A 0.7 cm tan-black, anthracotic lymph node is present in the attached fat. Representative sections to include mass and nearest inked resection margin are submitted for frozen section microscopy, now in cassette A1.

Representative sections of the remaining tissue are submitted as follows:

- 2 mass to inked resection margin;
- 3 mass to serosa;
- 4 mass to adjacent fat;
- 5-6 cysts adjacent to mass;
- 7 one whole lymph node bisected.

B. Received in formalin, labeled "superior thymus margin," is a 4.4 x 2.6 x 0.8 cm tan, lobulated, irregular fatty tissue. Sectioning reveals a tan, lobulated cut surface with no discrete lesions. Representative sections are submitted in two cassettes.

C. Received in formalin, labeled "lateral thymus," is a 2.4 x 1.9 x 0.5 cm tan, lobulated, irregular fatty tissue. The cut surface is tan, lobulated, with no discrete lesions. The specimen is entirely submitted in two cassettes.

D. Received fresh, labeled "pericardial phrenic margin," is a 0.3 x 0.2 x 0.2 cm tan, irregular soft tissue, submitted in toto for frozen section microscopy, now in cassette D.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Surgical Pathology Report

Taken: DOB: (Age: Gender: M

Criteria	11/5/13	Yes	No
HPA3 Discrepancy			
Immunohistochemistry			
Case is (circled)			
Interviewer Initials	SC		

Source: NCI Genomic Data Commons file 866a331e-7f6c-464a-9bb0-b74d12e159dd (TCGA-X7-A8M1.DCFFD40F-3E87-4576-9B6D-108704059271.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).